Gene-level copy-number profile of tumor specimen ALCH-AE7V-TTP1-A from ALCHEMIST case ALCH-AE7V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.1 years (22,691 days).
Specimen ALCH-AE7V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 23bce4ea-2b6f-47f6-b30e-02d825d437b6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE7V-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/9c1e058a-46bc-4762-b843-804dff1ad9c2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 991; copy number 2: 57,068; copy number 3: 230; copy number 4: 7; copy number 5: 8; copy number 6: 1; copy number 7: 6; copy number 9: 4; copy number 37: 1.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,487,951–3,611,508, 2 genes: MEGF6, MIR551A.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–2): AL139423.1.
- chr1:62,189,131–62,212,328, 5 genes: PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA.
- chr1:247,085,389–247,086,067, 1 gene: AL627095.1.
- chr2:232,378,724–232,536,667, 11 genes: ALPP, AC068134.1, ECEL1P2, ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1, PRSS56, CHRND.
- chr3:129,555,214–129,606,676, 2 genes (within-gene range 0–2): PLXND1, RN7SL752P.
- chr5:1,062,896–1,062,974, 1 gene (within-gene range 0–2): MIR4635.
- chr7:77,004,662–77,005,774, 1 gene (within-gene range 0–1): UPK3BP1.
- chr7:149,776,042–149,833,979, 1 gene: SSPOP.
- chr10:86,668,507–86,736,072, 1 gene: LDB3.
- chr10:117,542,445–117,549,546, 1 gene (within-gene range 0–2): EMX2.
- chr11:1,919,703–1,938,706, 1 gene: TNNT3.
- chr11:61,746,493–61,757,655, 1 gene (within-gene range 0–2): MYRF-AS1.
- chr14:21,287,939–21,351,301, 1 gene: RPGRIP1.
- chr14:92,905,697–92,907,482, 1 gene: LINC02287.
- chr14:104,085,686–104,115,582, 1 gene: ASPG.
- chr15:25,174,927–25,223,327, 27 genes (within-gene range 0–2): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29.
- chr15:75,674,322–75,712,848, 3 genes: CSPG4, AC105020.4, AC105020.1.
- chr17:39,637,090–39,670,475, 3 genes: STARD3, TCAP, PNMT.
- chr19:55,528,611–55,537,133, 1 gene: SBK2.
- chr20:62,302,093–62,308,862, 2 genes (within-gene range 0–2): ADRM1, AL354836.1.
- chr20:62,332,487–62,332,557, 1 gene (within-gene range 0–2): MIR4758.
- chr20:63,488,013–63,499,239, 1 gene: EEF1A2.
- chr22:20,198,729–20,321,203, 8 genes: AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3.
- chr22:29,711,820–29,731,833, 2 genes (within-gene range 0–2): AC004882.2, CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 20 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:1,947,278–2,001,470, 7 genes, copy number 6–37: MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr14:104,857,792–104,858,836, 1 gene, copy number 5: AL583810.1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 7 (within-gene range 2–7): LINC00313.
- chr22:18,178,038–18,345,899, 2 genes, copy number 9: FAM230D, GGTLC5P.
- chr22:18,605,355–18,757,906, 9 genes, copy number 5–9: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E.

Autosomal genes at a single copy (total copy number 1): 991. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
